Somatic mutation profile of tumor specimen TCGA-VD-A8KM-01A (aliquot TCGA-VD-A8KM-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KM, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.8 years (24,047 days).
Specimen TCGA-VD-A8KM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45e5590c-ee65-4c27-b781-dc7a15d4a20a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KM-10C (Blood Derived Normal), aliquot TCGA-VD-A8KM-10C-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e0fe8e7-203b-4709-bc69-1921f896024e

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 17/76 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782605316, CD1414752; called by muse, mutect2
- DTNA | c.2081+1G>A p.X694_splice | Splice Site (SNP) | VAF 9/44 reads (20%) | catalogued as COSV52008415; called by muse, mutect2, varscan2
- HHAT | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1183312420; called by muse, mutect2, varscan2
- MAP3K19 | c.3838G>A p.G1280R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779120521; called by muse, mutect2, varscan2
- MROH2B | c.2045del p.F682Sfs*2 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as COSV68181667; called by mutect2, varscan2
- PUM1 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368398894; called by muse, mutect2
- TTN | c.23503G>A p.V7835I (on ENST00000591111; = p.V6908I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | PolyPhen benign (0.012); catalogued as rs397517507, COSV60334381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.4198A>G p.M1400V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPIFB1 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MACF1 | c.4705G>C p.G1569R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.767G>C p.W256S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF197 | c.13A>G p.N5D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DYSF | c.1203C>T p.N401= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs757047049, COSV99247642; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDAP1L1 | c.1077C>T p.Y359= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100697664; called by muse, mutect2, varscan2
- ITPR2 | c.135C>T p.D45= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs1418631524; called by muse, mutect2, varscan2
- MCHR2 | c.762G>A p.L254= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs1177416702; called by muse, mutect2, varscan2
- RAB11FIP5 | c.786C>T p.S262= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs774431399; called by muse, mutect2, varscan2
- WDR25 | c.1509C>T p.R503= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
